FM case AD16393 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/f5c091ae-8c59-48cd-9fb0-0d1ccf1a0729

Male, 36.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
